Somatic mutation profile of tumor specimen 0DCFVV from CCDI case PBBMBM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (617 days).
Specimen 0DCFVV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d36a87b-a8a4-495c-abe9-21c1713ffd54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCFVP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eaf0227-f374-466f-ab70-f56e293ddabf

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBA1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 362/1382 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs281864895, CM004923; ClinVar: uncertain significance; called by muse, varscan2
- ELFN1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 270/530 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.404); called by muse, varscan2
- GLCE | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, varscan2
- SNAPC4 | c.-22_-21del | 5'UTR (DEL) | VAF 76/486 reads (16%) | catalogued as rs1436518702; called by pindel, varscan2
